Somatic mutation profile of tumor specimen TCGA-DD-AAC8-01A (aliquot TCGA-DD-AAC8-01A-11D-A40R-10) from TCGA case TCGA-DD-AAC8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 72.1 years (26,322 days).
Specimen TCGA-DD-AAC8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98f56a26-5c2c-4ecc-bfa4-454d05f72b72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAC8-10A (Blood Derived Normal), aliquot TCGA-DD-AAC8-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/694fe2ed-837b-49e8-b59d-5d54af5d7a00

The open-access MAF lists 600 somatic variants for this specimen: 478 protein-altering or splice-affecting, 111 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 411, Silent 111, Nonsense Mutation 27, Splice Site 25, Frame Shift Del 5, Splice Region 4, Intron 3, RNA 3, Frame Shift Ins 3, 3'Flank 2, 3'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 22/76 reads (29%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTNNB1 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 38/118 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 27/54 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960018, COSV67961061, COSV67962846; called by muse, mutect2, varscan2
- ABAT | c.598A>T p.N200Y | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99191040; called by muse, mutect2, varscan2
- ABCA4 | c.3171A>T p.E1057D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100933267; called by muse, mutect2, varscan2
- ABCA4 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.845); catalogued as COSV100933268; called by muse, mutect2, varscan2
- ABCC12 | c.1587+2T>A p.X529_splice | Splice Site (SNP) | VAF 36/50 reads (72%) | catalogued as COSV100253307; called by muse, mutect2, varscan2
- AC006059.2 | c.1960A>T p.N654Y | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV100045986; called by muse, mutect2, varscan2
- ACSL6 | c.611A>T p.Q204L (on ENST00000379240; = p.Q229L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV99734716; called by muse, mutect2, varscan2
- ACTG1 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.089); catalogued as COSV100112066; called by muse, varscan2
- ADAM23 | c.1567-2A>T p.X523_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100008898; called by muse, mutect2, varscan2
- ADAMTS2 | c.3435T>A p.N1145K | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.057); catalogued as COSV99283993; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4595G>T p.R1532L | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV99721324; called by muse, mutect2, varscan2
- ADAR | c.2773A>T p.S925C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99426783; called by muse, mutect2, varscan2
- ADCY1 | c.541A>T p.S181C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV99812947; called by muse, mutect2, varscan2
- ADD3 | c.831A>T p.Q277H | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV53325498, COSV99523754; called by muse, mutect2, varscan2
- ADGRF2 | c.1834T>A p.L612M (on ENST00000296862 / NM_001368115.2; = p.L544M on NM_153839.7) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99731806; called by muse, mutect2, varscan2
- ADGRG4 | c.5297A>T p.Q1766L | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99796904; called by muse, mutect2, varscan2
- ADGRV1 | c.7987T>A p.S2663T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV101316563; called by muse, mutect2, varscan2
- ADRA2A | c.1319T>C p.I440T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701814; called by muse, mutect2, varscan2
- AGR2 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV101290833; called by muse, mutect2, varscan2
- AHI1 | c.3290A>T p.Q1097L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV99663808; called by muse, mutect2, varscan2
- AHNAK2 | c.2099T>A p.V700E | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100319036; called by muse, mutect2, varscan2
- ALPG | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99779494; called by muse, mutect2, varscan2
- ALPP | c.635T>A p.L212H | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101235196; called by muse, mutect2, varscan2
- ALPP | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV101235197; called by muse, mutect2
- ANKRD1 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100792324; called by muse, mutect2, varscan2
- ANKRD12 | c.5123A>T p.H1708L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as COSV100042152; called by muse, mutect2, varscan2
- ANKRD26 | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 130/516 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101066658; called by muse, varscan2
- ANKRD35 | c.154T>A p.S52T | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.381); catalogued as COSV100841863; called by muse, mutect2, varscan2
- ANKRD55 | c.1310T>A p.L437H | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV100591678; called by muse, mutect2, varscan2
- ANXA9 | c.453C>G p.C151W | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100929176; called by muse, mutect2, varscan2
- API5 | c.1029_1030insTA p.E344* | Frame Shift Ins (INS) | VAF 46/218 reads (21%) | catalogued as COSV101124605; called by mutect2, pindel, varscan2
- APP | c.1991A>T p.E664V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV100696298; called by muse, mutect2, varscan2
- ARHGAP19 | c.257A>T p.K86M | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100363354; called by muse, mutect2, varscan2
- ARHGAP6 | c.1141T>A p.L381I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100273595; called by muse, mutect2, varscan2
- ARHGDIA | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV53907865; called by muse, mutect2
- ARHGEF11 | c.700A>T p.S234C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100810432; called by muse, mutect2
- ARID2 | c.300C>G p.Y100* | Nonsense Mutation (SNP) | VAF 41/75 reads (55%) | catalogued as COSV100537086, COSV57605451, COSV57608298; called by muse, mutect2, varscan2
- ARIH2 | c.625A>C p.K209Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100711417; called by muse, mutect2, varscan2
- ARMC8 | c.1823G>T p.G608V (on ENST00000469044 / NM_001363941.2; = p.G594V on NM_015396.6) | Missense Mutation (SNP) | VAF 138/250 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs761854872, COSV100509899; called by muse, mutect2, varscan2
- ARSI | c.1691T>A p.L564Q | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV100156124; called by muse, mutect2, varscan2
- ATF2 | c.1496A>T p.Q499L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99909038; called by muse, mutect2, varscan2
- ATP2B3 | c.3457A>T p.T1153S | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); catalogued as COSV99685940; called by muse, mutect2, varscan2
- ATP6V1B2 | c.386-2A>T p.X129_splice | Splice Site (SNP) | VAF 34/156 reads (22%) | catalogued as COSV99369610; called by muse, mutect2, varscan2
- ATR | c.1574A>T p.K525M | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100638609; called by muse, mutect2, varscan2
- ATRNL1 | c.2416-2A>G p.X806_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100372899; called by muse, mutect2, varscan2
- ATRX | c.5494G>C p.E1832Q | Missense Mutation (SNP) | VAF 117/134 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971495, COSV64870656; called by muse, mutect2, varscan2
- ATXN7 | c.1234A>T p.R412W | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99895390; called by muse, mutect2, varscan2
- BBS5 | c.682-2A>T p.X228_splice | Splice Site (SNP) | VAF 56/180 reads (31%) | catalogued as COSV99752240; called by muse, mutect2, varscan2
- BCAN | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100228519; called by muse, mutect2
- BCAS1 | c.1021A>T p.K341* | Nonsense Mutation (SNP) | VAF 53/209 reads (25%) | catalogued as COSV101006473; called by muse, mutect2, varscan2
- BCL11B | c.824C>T p.A275V (on ENST00000357195 / NM_001282237.2; = p.A204V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as rs1192807157, COSV100595955; called by muse, mutect2
- BEND2 | c.2348T>A p.L783Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101192710; called by muse, mutect2, varscan2
- BLMH | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99913237; called by muse, mutect2, varscan2
- BLMH | c.232T>A p.C78S | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99913238; called by muse, mutect2, varscan2
- BNC2 | c.3293T>A p.V1098E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV101037076; called by muse, mutect2, varscan2
- BPIFA1 | c.713T>A p.L238Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100845662; called by muse, mutect2, varscan2
- BPNT1 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV100435861; called by muse, mutect2
- BRD3 | c.1408-2A>T p.X470_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100325562; called by muse, mutect2
- BRINP3 | c.1294C>A p.Q432K | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs560983384, COSV100819522; called by muse, mutect2, varscan2
- C10orf71 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100110688; called by muse, mutect2, varscan2
- C12orf4 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.831); catalogued as COSV99712955; called by muse, mutect2, varscan2
- C8B | c.985A>T p.S329C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100980920; called by muse, mutect2, varscan2
- CA9 | c.592A>T p.N198Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100999908; called by muse, mutect2, varscan2
- CALHM1 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99588826; called by muse, mutect2, varscan2
- CASP4 | c.13A>T p.N5Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.51); catalogued as COSV67745059; called by muse, mutect2
- CASP8 | c.169A>T p.S57C | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV99966049; called by muse, mutect2, varscan2
- CATSPER1 | c.2033T>A p.L678Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100376272; called by muse, mutect2, varscan2
- CATSPER3 | c.343A>T p.N115Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99254334; called by muse, mutect2, varscan2
- CATSPERB | c.1907A>T p.Y636F | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV99831844; called by muse, mutect2, varscan2
- CCDC178 | c.685A>T p.I229L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100286910; called by muse, mutect2, varscan2
- CCDC80 | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV52815553; called by muse, mutect2, varscan2
- CCDC87 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100040200; called by muse, mutect2, varscan2
- CD101 | c.846A>T p.K282N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99870199; called by muse, mutect2, varscan2
- CD109 | c.2843A>C p.N948T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99754691; called by muse, mutect2, varscan2
- CD2BP2 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV99977025; called by muse, mutect2, varscan2
- CD44 | c.1173T>A p.S391R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99556035; called by muse, mutect2, varscan2
- CD5L | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100941198; called by muse, mutect2, varscan2
- CDC42BPB | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100775638; called by muse, mutect2, varscan2
- CDC45 | c.971A>T p.Q324L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99597067; called by muse, mutect2, varscan2
- CDH11 | c.2287A>T p.T763S | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.028); catalogued as COSV99219832; called by muse, mutect2, varscan2
- CDSN | c.887A>T p.Y296F | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99457284; called by muse, mutect2, varscan2
- CEACAM1 | c.562A>T p.S188C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99362636; called by muse, mutect2, varscan2
- CEACAM3 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99705129; called by muse, mutect2, varscan2
- CEACAM5 | c.1546A>T p.K516* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99704184; called by muse, mutect2, varscan2
- CELSR3 | c.7103A>T p.Q2368L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99375077; called by muse, mutect2, varscan2
- CENPC | c.2443G>C p.G815R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99894457; called by muse, mutect2, varscan2
- CENPE | c.5958A>T p.K1986N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.922); catalogued as COSV99479243; called by muse, mutect2, varscan2
- CENPI | c.1891A>C p.N631H | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99515881; called by mutect2, varscan2
- CFAP46 | c.6090G>C p.R2030S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as COSV99585622; called by muse, mutect2, varscan2
- CFAP77 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV100546154; called by muse, mutect2, varscan2
- CFAP92 | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99414962; called by muse, mutect2, varscan2
- CHST11 | c.622T>A p.F208I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359956; called by muse, mutect2, varscan2
- CLCNKA | c.1755A>T p.T585= | Splice Region (SNP) | VAF 60/80 reads (75%) | catalogued as COSV100510353; called by muse, mutect2, varscan2
- CLMP | c.751T>A p.L251M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV101507473; called by muse, mutect2, varscan2
- CLPP | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99832254; called by muse, mutect2, varscan2
- CLRN1 | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.787); catalogued as COSV100184683; called by muse, mutect2, varscan2
- CMTM4 | c.491A>T p.Y164F | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (1); PolyPhen possibly damaging (0.793); catalogued as COSV100411941; called by muse, mutect2, varscan2
- CNGA3 | c.559A>C p.I187L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV99737563; called by muse, mutect2, varscan2
- CNTNAP2 | c.976A>T p.S326C | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.855); catalogued as COSV100673280; called by muse, mutect2, varscan2
- COL1A2 | c.3051A>T p.R1017S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99801175; called by muse, mutect2, varscan2
- COL3A1 | c.2946A>T p.K982N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100483781, COSV58587451; called by muse, mutect2, varscan2
- COL4A5 | c.891+2T>A p.X297_splice | Splice Site (SNP) | VAF 125/289 reads (43%) | catalogued as COSV100090046; called by muse, mutect2, varscan2
- COMP | c.685T>A p.C229S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99721595; called by muse, mutect2, varscan2
- CR1 | c.3645C>G p.N1215K | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100888067; called by muse, mutect2, varscan2
- CRB1 | c.2947A>T p.R983W | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV66333216; called by muse, mutect2, varscan2
- CREB3L1 | c.365A>T p.K122I | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99915335; called by muse, mutect2, varscan2
- CRHR1 | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV99524199; called by muse, mutect2, varscan2
- CSMD1 | c.10324T>A p.S3442T (on ENST00000520002; = p.S3441T on NM_033225.6) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV100154040; called by muse, mutect2, varscan2
- CSMD3 | c.3850A>T p.R1284* (on ENST00000297405 / NM_001363185.1; = p.R1180* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 28/148 reads (19%) | catalogued as COSV99848707; called by muse, mutect2, varscan2
- CYP11B1 | c.191T>A p.L64Q | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99455752; called by muse, mutect2, varscan2
- CYP7B1 | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV100043056; called by muse, mutect2, varscan2
- CYTH1 | c.892-2A>T p.X298_splice | Splice Site (SNP) | VAF 25/123 reads (20%) | catalogued as COSV63123004; called by muse, mutect2, varscan2
- DACH1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV100499342; called by muse, mutect2, varscan2
- DAGLA | c.2761T>A p.F921I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV99944750; called by muse, mutect2, varscan2
- DAPK1 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100802777; called by muse, mutect2, varscan2
- DCAF17 | c.231-2A>T p.X77_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100930784; called by muse, mutect2, varscan2
- DDX60L | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as COSV99488525; called by muse, mutect2
- DEPDC1B | c.1073A>T p.Q358L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV99409903; called by muse, mutect2, varscan2
- DGKK | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV65706162; called by muse, mutect2, varscan2
- DHX9 | c.1541A>T p.H514L | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841533; called by muse, mutect2, varscan2
- DIDO1 | c.1402A>T p.K468* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99827229; called by muse, mutect2, varscan2
- DIRAS2 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV101005918; called by muse, mutect2, varscan2
- DKK3 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100485123; called by muse, mutect2, varscan2
- DLGAP1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756157301, COSV100233917; called by muse, mutect2, varscan2
- DNAH10 | c.3428A>T p.Y1143F (on ENST00000409039; = p.Y1082F on NM_207437.3) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV101292804; called by muse, mutect2, varscan2
- DNAH5 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99454512; called by muse, mutect2, varscan2
- DNAH5 | c.276A>T p.T92= | Splice Region (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99454513; called by muse, mutect2, varscan2
- DNAH5 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV99454514; called by muse, mutect2, varscan2
- DNASE1L1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1557187287, COSV50010782; called by muse, mutect2, varscan2
- DNM1 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1414107946, COSV100360372; called by muse, mutect2, varscan2
- DOCK2 | c.2279G>A p.G760D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.898); catalogued as COSV56962657, COSV99915647; called by muse, mutect2, varscan2
- DOCK3 | c.1396T>A p.S466T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV99815300; called by muse, mutect2, varscan2
- DSCAML1 | c.4039A>T p.K1347* (on ENST00000321322; = p.K1287* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100357333; called by muse, mutect2, varscan2
- DTX2 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184869; called by muse, varscan2
- EGF | c.2918A>C p.D973A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99491387; called by muse, mutect2, varscan2
- EIPR1 | c.112A>T p.K38* | Nonsense Mutation (SNP) | VAF 58/199 reads (29%) | catalogued as rs761387020, COSV101182289; called by muse, mutect2, varscan2
- ELANE | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as rs773808780, COSV99708826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELP4 | c.1006A>T p.R336* (on ENST00000350638; = p.R335* on NM_019040.5) | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | catalogued as COSV100635906; called by muse, mutect2, varscan2
- EMILIN3 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV100182831; called by muse, mutect2, varscan2
- EPB41L3 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1350949619, COSV59447862; called by muse, mutect2, varscan2
- EPHB3 | c.346T>A p.C116S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100383300, COSV57808698; called by muse, mutect2, varscan2
- ESX1 | c.320A>T p.K107M | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.926); catalogued as COSV101006513; called by muse, mutect2, varscan2
- ESYT3 | c.798T>A p.D266E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100004987; called by muse, mutect2, varscan2
- ETFDH | c.360T>G p.D120E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100310127; called by muse, mutect2, varscan2
- ETV5 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100112607; called by muse, mutect2, varscan2
- EVC | c.2108T>A p.V703E | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99382636; called by muse, mutect2, varscan2
- EXT2 | c.1663-2A>T p.X555_splice (on ENST00000343631; = p.X588_splice on NM_000401.3) | Splice Site (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100640698; called by muse, mutect2, varscan2
- FAM169A | c.774A>T p.L258F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV100998425; called by muse, mutect2, varscan2
- FAM171B | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.191); catalogued as rs747728735, COSV100489042; called by muse, mutect2, varscan2
- FAT2 | c.3943A>T p.T1315S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.57); catalogued as rs1241571534, COSV99944183; called by muse, mutect2, varscan2
- FAT4 | c.8572A>T p.T2858S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100630299; called by muse, mutect2, varscan2
- FBXL7 | c.977T>A p.I326N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV100310964; called by muse, mutect2, varscan2
- FCRLB | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100396389; called by muse, mutect2, varscan2
- FGD3 | c.959A>T p.D320V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490920; called by muse, mutect2, varscan2
- FHOD1 | c.2921T>C p.M974T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV99264539; called by muse, mutect2, varscan2
- FKBP6 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV99333745; called by muse, mutect2, varscan2
- FLNB | c.4085G>T p.G1362V | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99915025; called by muse, mutect2, varscan2
- FOXP2 | c.1594A>T p.S532C | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100647430; called by muse, mutect2, varscan2
- FRAS1 | c.5783A>G p.H1928R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as rs1471365312, COSV99356005; called by muse, mutect2, varscan2
- FRAS1 | c.11041A>T p.T3681S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.257); catalogued as COSV99356006; called by muse, mutect2
- FSCN1 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100435298; called by muse, mutect2, varscan2
- FUT5 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747185407, COSV53135767, COSV99399012; called by muse, mutect2, varscan2
- FYB1 | c.1830T>A p.S610R | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100686461; called by muse, mutect2, varscan2
- FZD7 | c.1057T>A p.W353R | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637479; called by muse, varscan2
- FZD7 | c.1138T>A p.Y380N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99637480; called by muse, varscan2
- GABRG3 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV100408778, COSV100410042; called by muse, mutect2, varscan2
- GFPT1 | c.409-1G>A p.X137_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100623000; called by muse, mutect2, varscan2
- GGT5 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99571319, COSV99571914; called by muse, mutect2, varscan2
- GJA5 | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99605831; called by muse, mutect2, varscan2
- GJC2 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100813009; called by muse, mutect2, varscan2
- GLDC | c.1360G>T p.A454S | Missense Mutation (SNP) | VAF 169/290 reads (58%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as COSV100394634; called by muse, mutect2, varscan2
- GLIS1 | c.874T>A p.Y292N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100390979; called by muse, mutect2, varscan2
- GPR101 | c.13T>A p.C5S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as COSV99981637; called by muse, mutect2, varscan2
- GPR12 | c.744A>T p.K248N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV101198026; called by muse, mutect2, varscan2
- GPX5 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs532584620, COSV69079477; called by muse, mutect2, varscan2
- GRIA1 | c.1573A>T p.K525* | Nonsense Mutation (SNP) | VAF 34/151 reads (23%) | catalogued as COSV99602516; called by muse, mutect2, varscan2
- GRID1 | c.2209T>G p.Y737D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026731; called by muse, mutect2, varscan2
- GUCY2D | c.1688A>T p.K563M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644298; called by muse, mutect2, varscan2
- HDGFL3 | c.196A>G p.K66E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100220946; called by muse, mutect2, varscan2
- HHATL | c.1047-2A>T p.X349_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99825795; called by muse, mutect2, varscan2
- HIF1A | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100049301; called by muse, mutect2, varscan2
- HLA-G | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 101/149 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100827202; called by muse, mutect2, varscan2
- HORMAD1 | c.501A>T p.L167F | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100464453; called by muse, mutect2, varscan2
- HORMAD1 | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 212/854 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100464462; called by muse, mutect2, varscan2
- HOXB8 | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99494215; called by muse, mutect2, varscan2
- HRNR | c.2245T>A p.S749T | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV100913979; called by muse, mutect2, varscan2
- IBTK | c.2314A>T p.M772L | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100091537; called by muse, mutect2, varscan2
- IFNA7 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as rs112551811; called by muse, mutect2, varscan2
- IGF1R | c.467A>T p.D156V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163204; called by muse, mutect2, varscan2
- IGF2BP2 | c.1105A>T p.S369C | Missense Mutation (SNP) | VAF 103/406 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV100649543; called by muse, mutect2, varscan2
- IGFL3 | c.79+2T>A p.X27_splice | Splice Site (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100407976; called by muse, mutect2, varscan2
- IL17REL | c.44T>A p.M15K | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100377474; called by muse, mutect2, varscan2
- IL18RAP | c.964A>T p.I322F | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99962440; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1443A>T p.R481S | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100782086; called by muse, mutect2, varscan2
- ILDR2 | c.350A>T p.Y117F | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99614499; called by muse, mutect2, varscan2
- IMPACT | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 103/281 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99408921; called by muse, mutect2, varscan2
- IQGAP1 | c.4688A>G p.Y1563C | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99185381; called by muse, mutect2, varscan2
- IQGAP3 | c.2207A>T p.Q736L | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100752397; called by muse, mutect2, varscan2
- IWS1 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV99767534; called by muse, mutect2, varscan2
- IZUMO2 | c.384T>A p.Y128* | Nonsense Mutation (SNP) | VAF 59/183 reads (32%) | catalogued as COSV99518392; called by muse, mutect2, varscan2
- JAM2 | c.241+2T>C p.X81_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100468834; called by muse, mutect2, varscan2
- KBTBD12 | c.1870T>A p.*624Kext*35 | Nonstop Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV100675536; called by muse, mutect2
- KCNA2 | c.854A>T p.Q285L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV100316134; called by muse, mutect2, varscan2
- KCNG3 | c.283T>A p.Y95N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100045485; called by muse, mutect2, varscan2
- KCNH2 | c.3330G>T p.Q1110H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV100061143; called by muse, mutect2, varscan2
- KCNK2 | c.1253A>G p.E418G (on ENST00000444842 / NM_001017425.3; = p.E403G on NM_014217.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV101222345; called by muse, mutect2, varscan2
- KIAA1210 | c.1141A>T p.S381C | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101274410; called by muse, mutect2, varscan2
- KIAA1549L | c.2333T>A p.L778Q (on ENST00000321505; = p.L1075Q on NM_012194.3) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99684524; called by muse, mutect2, varscan2
- KLHL23 | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99776131; called by muse, mutect2, varscan2
- KLK10 | c.259T>A p.C87S | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100011304; called by muse, mutect2, varscan2
- KLRK1 | c.203T>A p.I68N | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs377167821; called by muse, mutect2, varscan2
- KNG1 | c.1726A>G p.I576V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99405881; called by muse, mutect2
- KRT17 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100245265; called by muse, varscan2
- KRT35 | c.712-2A>T p.X238_splice | Splice Site (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99877939; called by muse, mutect2, varscan2
- KRTAP5-6 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV101191785; called by muse, mutect2, varscan2
- KRTAP9-3 | c.12T>A p.C4* | Nonsense Mutation (SNP) | VAF 32/232 reads (14%) | catalogued as COSV100893256; called by muse, mutect2, varscan2
- LAMA5 | c.2578A>T p.S860C | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53352175, COSV99442476; called by muse, mutect2, varscan2
- LAMC2 | c.2917A>T p.M973L | Missense Mutation (SNP) | VAF 121/459 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99918004; called by muse, mutect2, varscan2
- LAPTM5 | c.563T>A p.M188K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99612696; called by muse, mutect2, varscan2
- LDB1 | c.181A>T p.T61S (on ENST00000425280 / NM_001321612.2; = p.T25S on NM_003893.5) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV100756466; called by muse, mutect2, varscan2
- LDLRAD3 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as COSV100215309; called by muse, mutect2, varscan2
- LIPI | c.185T>A p.I62K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100754033; called by muse, mutect2, varscan2
- LNPEP | c.1319A>T p.E440V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99183628; called by muse, mutect2, varscan2
- LRRC66 | c.2207A>T p.Q736L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.226); catalogued as COSV58631866; called by muse, mutect2, varscan2
- LRRK2 | c.7469A>T p.Q2490L | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100111195; called by muse, mutect2, varscan2
- M1AP | c.56A>T p.Q19L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV99304537; called by muse, mutect2, varscan2
- MACC1 | c.985T>A p.Y329N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100256312; called by muse, mutect2, varscan2
- MACF1 | c.6879A>T p.L2293F | Missense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as COSV99247017; called by muse, mutect2, varscan2
- MACF1 | c.11909A>T p.K3970M (on ENST00000372915; = p.K1903M on NM_012090.5) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99247019; called by muse, mutect2, varscan2
- MAP1B | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.985); catalogued as COSV99702965; called by muse, mutect2, varscan2
- MAP1B | c.2642A>T p.E881V | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV99702966; called by muse, mutect2, varscan2
- MAP2 | c.2937A>T p.K979N | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99561829; called by muse, mutect2, varscan2
- MAP3K15 | c.1928T>A p.L643* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100135789; called by muse, mutect2, varscan2
- MARK4 | c.1396A>T p.S466C | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99488899; called by muse, mutect2, varscan2
- MATN3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 106/161 reads (66%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101337477; called by muse, mutect2, varscan2
- MCM10 | c.580A>G p.K194E (on ENST00000484800 / NM_182751.3; = p.K193E on NM_018518.5) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV101098466; called by muse, mutect2, varscan2
- MCM10 | c.2230A>G p.I744V (on ENST00000484800 / NM_182751.3; = p.I743V on NM_018518.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV101098468; called by muse, mutect2, varscan2
- MCM6 | c.1796A>T p.K599I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs764296916, COSV99919398; called by muse, mutect2, varscan2
- MCTP1 | c.1739T>A p.L580Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56517064; called by muse, mutect2, varscan2
- MCTP1 | c.779T>A p.M260K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV100388257; called by muse, mutect2, varscan2
- MDM1 | c.858dup p.H287Tfs*4 | Frame Shift Ins (INS) | VAF 20/91 reads (22%) | catalogued as rs1468966270; called by mutect2, pindel, varscan2
- MECOM | c.697A>T p.N233Y (on ENST00000468789 / NM_001105078.4; = p.N421Y on NM_004991.4) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99245550; called by muse, varscan2
- MGAT1 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | PolyPhen probably damaging (0.948); catalogued as COSV100286844; called by muse, mutect2, varscan2
- MKRN1 | c.220A>T p.N74Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99751907; called by muse, mutect2, varscan2
- MMD2 | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs1027956978, COSV101287164; called by muse, mutect2, varscan2
- MMP14 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs202185020, COSV100314329; called by muse, mutect2, varscan2
- MPEG1 | c.1626T>G p.D542E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV99915971; called by muse, mutect2, varscan2
- MROH2B | c.1643T>A p.L548Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV101270937; called by muse, mutect2, varscan2
- MROH9 | c.30T>A p.S10R | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100883073; called by muse, mutect2
- MT1M | c.132T>A p.C44* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99319335; called by muse, mutect2, varscan2
- MTMR9 | c.1365G>A p.M455I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99644615; called by muse, mutect2, varscan2
- MUC6 | c.5086T>A p.S1696T | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV101424808; called by muse, mutect2, varscan2
- MVP | c.578-2A>T p.X193_splice | Splice Site (SNP) | VAF 23/92 reads (25%) | catalogued as COSV100651749; called by muse, mutect2, varscan2
- MYEF2 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.714); catalogued as COSV99982224; called by muse, mutect2, varscan2
- MYH4 | c.2861T>A p.L954H | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99702324; called by muse, mutect2, varscan2
- MYH4 | c.2705T>A p.L902* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV99702327; called by muse, mutect2, varscan2
- MYO16 | c.1484T>A p.L495H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51791751, COSV99194700; called by muse, mutect2, varscan2
- MYO1H | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.177); catalogued as rs757399287, COSV100184045; called by muse, mutect2, varscan2
- MYO3A | c.1597T>A p.Y533N | Missense Mutation (SNP) | VAF 89/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99781701; called by muse, mutect2, varscan2
- MYO9B | c.880A>T p.S294C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101261970; called by muse, mutect2, varscan2
- MYOF | c.5765A>T p.D1922V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100826147; called by muse, mutect2, varscan2
- MYOM1 | c.4894A>T p.T1632S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.318); catalogued as COSV99868505; called by muse, mutect2, varscan2
- MYOM1 | c.4157A>T p.E1386V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99868511; called by muse, mutect2, varscan2
- MYOM2 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100038177, COSV100038228; called by muse, mutect2, varscan2
- NASP | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100602020; called by muse, varscan2
- NDUFB7 | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs747768995, COSV99295267; called by muse, mutect2, varscan2
- NELFB | c.1629A>T p.P543= | Splice Region (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100547063; called by muse, mutect2, varscan2
- NEURL4 | c.2300A>T p.Q767L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100223324; called by muse, mutect2, varscan2
- NFASC | c.1801G>T p.D601Y (on ENST00000339876 / NM_001378329.1; = p.D612Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs768967076, COSV58363929; called by muse, mutect2, varscan2
- NLRP2 | c.3082A>T p.N1028Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99672685; called by muse, mutect2, varscan2
- NME7 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 110/907 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs777597073, COSV100891208; called by muse, mutect2, varscan2
- NOL4 | c.1448A>T p.H483L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99308540; called by muse, mutect2, varscan2
- NPFFR2 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100441325; called by muse, mutect2, varscan2
- NR1D2 | c.518-2A>T p.X173_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100437598; called by muse, mutect2
- NXF3 | c.442T>A p.Y148N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101222085; called by muse, mutect2, varscan2
- NYNRIN | c.3851T>A p.L1284Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV101230707; called by muse, mutect2, varscan2
- OBSCN | c.16001A>T p.Y5334F | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.103); catalogued as rs753275811, COSV99484601; called by muse, mutect2, varscan2
- OBSCN | c.18872T>A p.L6291H | Missense Mutation (SNP) | VAF 65/538 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.253); catalogued as COSV99484602; called by muse, mutect2, varscan2
- OPRK1 | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV99654412; called by muse, mutect2, varscan2
- OR10K2 | c.413A>T p.H138L | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs754880009, COSV100149665; called by mutect2, varscan2
- OR11H12 | c.468T>A p.C156* | Nonsense Mutation (SNP) | VAF 25/440 reads (6%) | catalogued as COSV101612501, COSV101612535; called by muse, mutect2
- OR14I1 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100700544; called by muse, mutect2, varscan2
- OR1A2 | c.259T>A p.L87M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV101126391; called by muse, mutect2, varscan2
- OR2A25 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV101376422; called by muse, mutect2, varscan2
- OR2G6 | c.453C>A p.S151R | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs774470186, COSV100598332, COSV58573644; called by muse, mutect2, varscan2
- OR2L2 | c.776T>A p.V259E | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100824346; called by muse, mutect2, varscan2
- OR51L1 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV100386496; called by muse, mutect2, varscan2
- OR52E2 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100384940; called by muse, mutect2, varscan2
- OR56A4 | c.232T>A p.W78R | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100417709; called by muse, mutect2, varscan2
- OR5F1 | c.530T>A p.F177Y | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV99558951; called by muse, mutect2, varscan2
- OR5K2 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.976); catalogued as COSV101415988; called by muse, mutect2, varscan2
- ORC3 | c.1994A>C p.N665T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100006321; called by muse, mutect2, varscan2
- OSBPL7 | c.1820A>T p.K607M | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99137073; called by muse, mutect2, varscan2
- OTOL1 | c.811A>T p.S271C | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.386); catalogued as COSV100020282; called by muse, mutect2, varscan2
- PAX8 | c.101T>A p.I34N | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM065371, COSV99640136; called by muse, mutect2, varscan2
- PCDHB11 | c.2095T>A p.S699T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.175); catalogued as COSV100697192, COSV61313390; called by muse, mutect2, varscan2
- PCDHB6 | c.2119G>T p.V707L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99171453; called by muse, mutect2, varscan2
- PCDHB7 | c.466A>T p.S156C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.078); catalogued as COSV99177444; called by muse, mutect2, varscan2
- PCDHGA5 | c.351T>A p.Y117* | Nonsense Mutation (SNP) | VAF 37/166 reads (22%) | catalogued as COSV99547530; called by muse, mutect2, varscan2
- PCLO | c.13231A>G p.T4411A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.414); catalogued as COSV100438203; called by muse, mutect2, varscan2
- PDE5A | c.1565C>A p.T522K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99309232; called by muse, mutect2, varscan2
- PDE9A | c.1735A>T p.R579* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99372259; called by muse, mutect2, varscan2
- PDILT | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0.299); catalogued as COSV100199857; called by muse, mutect2, varscan2
- PDS5B | c.2708A>T p.Q903L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100221559; called by muse, mutect2, varscan2
- PHF14 | c.2136A>T p.E712D | Missense Mutation (SNP) | VAF 110/410 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.543); catalogued as COSV101301864; called by muse, mutect2, varscan2
- PI4KB | c.1210C>T p.L404F (on ENST00000368873 / NM_001369623.1; = p.L416F on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1456044414, COSV99650207; called by muse, mutect2, varscan2
- PICK1 | c.154-2A>C p.X52_splice | Splice Site (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100811119; called by muse, mutect2, varscan2
- PIGC | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99278417; called by muse, mutect2, varscan2
- PIK3AP1 | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV100226245; called by muse, mutect2, varscan2
- PIK3CB | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs202220571, COSV56692029; called by muse, mutect2, varscan2
- PKN3 | c.656A>T p.Q219L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99403945; called by muse, mutect2, varscan2
- PLA2G3 | c.206A>T p.Q69L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99312095; called by muse, mutect2, varscan2
- PLCH2 | c.3679A>T p.R1227W | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV99617198; called by muse, mutect2, varscan2
- PLD1 | c.659A>T p.K220M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100578945; called by muse, mutect2, varscan2
- PLEKHO1 | c.146A>T p.K49I | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99215432; called by muse, mutect2, varscan2
- PLXNA4 | c.842T>A p.V281E | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327285; called by muse, mutect2, varscan2
- PLXNB1 | c.4534A>T p.R1512W | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV99603464; called by muse, mutect2, varscan2
- PNMT | c.395T>A p.L132H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV99510807; called by muse, mutect2, varscan2
- PNPLA6 | c.3916A>T p.S1306C (on ENST00000414982 / NM_001166111.2; = p.S1258C on NM_006702.5) | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV99654568; called by muse, mutect2, varscan2
- POLA1 | c.2053A>T p.T685S | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV100985680; called by muse, mutect2, varscan2
- POLE | c.4913A>T p.N1638I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs771399151, COSV100268364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLQ | c.6899A>T p.E2300V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99953033; called by muse, mutect2, varscan2
- POLQ | c.808A>T p.N270Y | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99953034; called by muse, mutect2, varscan2
- POLQ | c.632-1G>C p.X211_splice | Splice Site (SNP) | VAF 95/186 reads (51%) | catalogued as COSV99953036; called by muse, mutect2, varscan2
- POLR1A | c.1351A>T p.I451F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs780550096, COSV99808475; called by muse, mutect2, varscan2
- POMT2 | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV99836722; called by muse, mutect2, varscan2
- POTEE | c.2762T>A p.L921Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); catalogued as COSV100389055; called by muse, mutect2, varscan2
- PPP4R3A | c.1217A>T p.Q406L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV100466565; called by muse, mutect2, varscan2
- PRG4 | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV100825960; called by muse, mutect2, varscan2
- PRKCG | c.1093-2A>T p.X365_splice | Splice Site (SNP) | VAF 44/145 reads (30%) | catalogued as COSV54730078, COSV99669560; called by muse, mutect2, varscan2
- PRSS1 | c.209A>T p.Q70L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100298506; called by muse, varscan2
- PRSS57 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV100249698; called by muse, mutect2, varscan2
- PRTG | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101221496; called by muse, mutect2, varscan2
- PRUNE1 | c.1165A>T p.R389W | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV99639985; called by muse, mutect2
- PSG2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1362039130, COSV100283729; called by muse, mutect2, varscan2
- PSG6 | c.465A>T p.L155F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.268); catalogued as COSV99414615; called by muse, mutect2, varscan2
- PTGFR | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882360; called by muse, mutect2, varscan2
- PTGS1 | c.1226A>T p.N409I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99793563; called by muse, mutect2, varscan2
- PTPRD | c.4751A>T p.H1584L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV100647181; called by muse, mutect2, varscan2
- PTPRD | c.191T>G p.V64G | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100645174, COSV100647182; called by muse, mutect2
- QRICH1 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58708029; called by muse, mutect2
- RACGAP1 | c.1228A>T p.S410C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100407986; called by muse, mutect2, varscan2
- RAG2 | c.1235A>T p.E412V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100271518, COSV57558399; called by muse, mutect2, varscan2
- RANBP2 | c.339A>T p.R113S | Missense Mutation (SNP) | VAF 174/716 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV99313392; called by muse, mutect2, varscan2
- RASGRF1 | c.2849C>A p.A950D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV101174797; called by muse, mutect2, varscan2
- RC3H1 | c.1395A>T p.Q465H | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.93); catalogued as COSV99281797; called by muse, mutect2, varscan2
- RGL1 | c.1030A>T p.K344* (on ENST00000360851 / NM_001297672.2; = p.K379* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/117 reads (12%) | catalogued as COSV100487799; called by muse, mutect2, varscan2
- RGS12 | c.3034-2A>T p.X1012_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100123378; called by muse, mutect2, varscan2
- RGS2 | c.19T>A p.L7M | Missense Mutation (SNP) | VAF 109/746 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV99343478; called by muse, mutect2, varscan2
- RHOB | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99695370; called by muse, mutect2, varscan2
- RIN3 | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV99380076; called by muse, mutect2, varscan2
- RNF31 | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV99396300; called by muse, mutect2, varscan2
- RPL18A | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99714511; called by muse, mutect2, varscan2
- RSF1 | c.778A>G p.M260V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1374823422, COSV100408020; called by muse, mutect2, varscan2
- RUFY1 | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 111/451 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100106493; called by muse, mutect2, varscan2
- RYR1 | c.4103A>T p.Q1368L | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV100617094; called by muse, mutect2, varscan2
- RYR2 | c.701T>A p.L234H | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100773088; called by muse, mutect2, varscan2
- RYR2 | c.8280T>A p.Y2760* | Nonsense Mutation (SNP) | VAF 19/164 reads (12%) | catalogued as COSV100773090; called by muse, mutect2, varscan2
- S100A3 | c.223T>A p.Y75N | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100573157; called by muse, mutect2, varscan2
- SAP130 | c.1857A>T p.S619= | Splice Region (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99385345; called by muse, mutect2, varscan2
- SBF2 | c.2861A>T p.K954M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99815839; called by muse, mutect2, varscan2
- SCAF1 | c.2362A>T p.R788W | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100862301; called by muse, mutect2, varscan2
- SCNN1G | c.1060T>A p.S354T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100264553; called by muse, mutect2, varscan2
- SCP2D1 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99602219; called by muse, mutect2, varscan2
- SEMA3A | c.545T>C p.I182T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.13); catalogued as COSV54893298, COSV99548043; called by muse, mutect2, varscan2
- SEMA4D | c.1969A>T p.T657S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100358842; called by muse, mutect2, varscan2
- SH3RF3 | c.832T>A p.C278S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100513889; called by muse, mutect2, varscan2
- SHROOM4 | c.1870C>A p.Q624K | Missense Mutation (SNP) | VAF 63/70 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99174762; called by muse, mutect2, varscan2
- SI | c.3993G>T p.W1331C | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100017291; called by muse, mutect2, varscan2
- SIGLEC11 | c.1922A>T p.E641V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101357096; called by muse, mutect2, varscan2
- SLAMF9 | c.262T>G p.F88V | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV100928201; called by muse, mutect2, varscan2
- SLC22A12 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100327932; called by muse, mutect2, varscan2
- SLC25A46 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.622); catalogued as COSV100582687; called by muse, mutect2, varscan2
- SLC26A9 | c.800T>A p.V267E | Missense Mutation (SNP) | VAF 123/212 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1344981323, COSV100536829; called by muse, mutect2, varscan2
- SLC4A7 | c.364A>T p.R122* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99840390; called by muse, mutect2
- SLC5A8 | c.1516A>T p.N506Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101610614; called by muse, mutect2, varscan2
- SLC6A13 | c.1217A>T p.Y406F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100570091; called by muse, mutect2, varscan2
- SLC7A6OS | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.785); catalogued as COSV99862389; called by muse, mutect2, varscan2
- SLC9A4 | c.2123A>T p.Q708L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV99763593; called by muse, mutect2, varscan2
- SLC9C2 | c.1708A>T p.I570L | Missense Mutation (SNP) | VAF 150/1134 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100877022; called by muse, mutect2, varscan2
- SLCO5A1 | c.2015T>A p.V672E | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99481105; called by muse, mutect2, varscan2
- SLFN12 | c.1596A>T p.K532N | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100513236; called by muse, mutect2, varscan2
- SOGA3 | c.158C>A p.T53K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV100847079; called by muse, mutect2, varscan2
- SPATA31A1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); catalogued as rs1396581641; called by muse, mutect2, varscan2
- SPSB4 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100141771; called by muse, mutect2, varscan2
- SPTBN1 | c.6488A>T p.E2163V | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV100443459; called by muse, mutect2, varscan2
- SRRM2 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100071550; called by muse, mutect2, varscan2
- STAB2 | c.2647-2A>T p.X883_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV101186361; called by muse, mutect2, varscan2
- STAT4 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV61827835, COSV61828418; called by muse, mutect2, varscan2
- STK32B | c.1192G>C p.G398R | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as rs558465928, COSV51474801, COSV99287498; called by muse, mutect2, varscan2
- SUN5 | c.901A>T p.M301L | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100644918; called by muse, mutect2, varscan2
- SVEP1 | c.8242A>T p.I2748F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV99929887; called by muse, mutect2, varscan2
- SYNE1 | c.14636G>T p.C4879F (on ENST00000367255 / NM_182961.4; = p.C4808F on NM_033071.3) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99579996; called by muse, mutect2, varscan2
- TACC2 | c.6464A>T p.Q2155L (on ENST00000334433; = p.Q233L on NM_006997.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV99587795; called by muse, mutect2, varscan2
- TACR3 | c.1102A>T p.K368* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as rs1353399295, COSV100511039; called by muse, mutect2, varscan2
- TAF1L | c.2879C>A p.A960D | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99645314, COSV99645448; called by muse, mutect2, varscan2
- TBC1D14 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV101299054; called by muse, mutect2, varscan2
- TDRD10 | c.926T>A p.L309Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99427702; called by muse, mutect2, varscan2
- TESPA1 | c.680T>C p.L227P (on ENST00000316577 / NM_001098815.3; = p.L89P on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100345692; called by muse, mutect2, varscan2
- TEX11 | c.455T>A p.L152Q (on ENST00000344304; = p.L137Q on NM_031276.3) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100722250; called by muse, mutect2, varscan2
- TG | c.1031A>T p.K344M | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99603373; called by muse, mutect2, varscan2
- TG | c.1785A>T p.L595F | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as COSV99603374; called by muse, mutect2, varscan2
- TG | c.3491G>T p.G1164V | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760317901, COSV99603377; called by muse, mutect2, varscan2
- TGFB1I1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100691241; called by muse, mutect2, varscan2
- THBS1 | c.3266A>T p.Q1089L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99528462; called by muse, mutect2, varscan2
- TIAM2 | c.1438A>T p.T480S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as COSV100020243; called by muse, mutect2, varscan2
- TIGD5 | c.1453T>G p.F485V | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99643678; called by muse, mutect2, varscan2
- TLN1 | c.4664G>T p.R1555L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV100147668, COSV100148271; called by muse, mutect2, varscan2
- TLR7 | c.2587T>A p.Y863N | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV101028161; called by muse, mutect2, varscan2
- TMCC1 | c.1597A>G p.M533V (on ENST00000393238 / NM_001349268.2; = p.M209V on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100261335; called by muse, mutect2, varscan2
- TMEM17 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs199885237, COSV100107831; called by muse, mutect2
- TMEM200C | c.1424T>A p.L475H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101274868; called by muse, mutect2, varscan2
- TMEM202 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100499275; called by muse, mutect2, varscan2
- TMEM26 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101051725; called by muse, mutect2, varscan2
- TMEM63B | c.1122-2A>T p.X374_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99442124; called by muse, mutect2, varscan2
- TNFRSF21 | c.1714A>T p.R572W | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99730276; called by muse, mutect2, varscan2
- TNFRSF25 | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100557177; called by muse, mutect2, varscan2
- TNRC6C | c.2327A>T p.E776V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100050711; called by muse, varscan2
- TRDN | c.455A>T p.E152V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100523453; called by muse, mutect2, varscan2
- TRIM67 | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100792213; called by muse, mutect2, varscan2
- TRIP12 | c.3131G>T p.S1044I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99390980; called by muse, mutect2, varscan2
- TRPC6 | c.2793A>T p.R931S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100723770; called by muse, mutect2, varscan2
- TRPC6 | c.403A>T p.N135Y | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100723771; called by muse, mutect2, varscan2
- TRPV5 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 99/166 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748929030, COSV99521078; called by muse, mutect2, varscan2
- TTC27 | c.317A>T p.Q106L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100513641; called by muse, mutect2, varscan2
- TTN | c.85228T>A p.W28410R (on ENST00000591111; = p.W20986R on NM_003319.4) | Missense Mutation (SNP) | VAF 38/118 reads (32%) | PolyPhen probably damaging (0.999); catalogued as COSV100631400; called by muse, mutect2, varscan2
- TTN | c.66221T>A p.V22074D (on ENST00000591111; = p.V14650D on NM_003319.4) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | PolyPhen possibly damaging (0.79); catalogued as rs759011433, COSV100631405; called by muse, mutect2, varscan2
- TUBA3C | c.248A>C p.Y83S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV101262844; called by muse, mutect2, varscan2
- TXNDC17 | c.353T>G p.M118R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99854666; called by muse, mutect2, varscan2
- UBAP2L | c.1690A>T p.N564Y | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV99672389; called by muse, mutect2, varscan2
- UBE2U | c.278T>A p.L93* | Nonsense Mutation (SNP) | VAF 94/254 reads (37%) | catalogued as COSV100934534; called by muse, mutect2, varscan2
- UBE3B | c.241A>T p.R81W | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1205668914, COSV99784504; called by muse, mutect2, varscan2
- UPK3B | c.721A>C p.T241P (on ENST00000257632; = p.L212= on NM_001347684.2) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV99991196; called by muse, mutect2, varscan2
- VASH2 | c.733A>G p.K245E (on ENST00000517399 / NM_001301056.2; = p.K201E on NM_024749.5) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99663720; called by muse, mutect2
- VIRMA | c.1381A>T p.K461* | Nonsense Mutation (SNP) | VAF 48/110 reads (44%) | catalogued as COSV99889537; called by muse, mutect2, varscan2
- VWC2L | c.589A>T p.I197F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV100436394; called by muse, mutect2, varscan2
- WASHC2A | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782121168, COSV99254807; called by muse, mutect2, varscan2
- WDR64 | c.1294T>A p.S432T | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV100844073; called by muse, mutect2, varscan2
- WFIKKN2 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100260126; called by muse, mutect2, varscan2
- WIF1 | c.131A>T p.Q44L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99683451; called by muse, mutect2, varscan2
- WIPF1 | c.1220T>A p.V407E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV99769522; called by muse, mutect2, varscan2
- XKR5 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.315); catalogued as COSV101306750; called by muse, mutect2, varscan2
- XPO5 | c.1252A>T p.S418C | Missense Mutation (SNP) | VAF 112/152 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99541461; called by muse, mutect2, varscan2
- XXYLT1 | c.653-2A>T p.X218_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100118766; called by muse, mutect2, varscan2
- ZBED9 | c.3537T>A p.S1179R | Missense Mutation (SNP) | VAF 199/283 reads (70%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.01); catalogued as COSV101509403; called by muse, mutect2, varscan2
- ZBP1 | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100474018; called by muse, mutect2, varscan2
- ZBTB41 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.044); catalogued as COSV100963460; called by muse, mutect2, varscan2
- ZBTB49 | c.885A>T p.Q295H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.346); catalogued as COSV100552621; called by muse, mutect2, varscan2
- ZFHX4 | c.1464A>C p.L488F | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.656); catalogued as rs1376395182, COSV99268091; called by muse, mutect2, varscan2
- ZFHX4 | c.7280C>T p.P2427L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs760554402, COSV99262250; called by muse, mutect2, varscan2
- ZFR2 | c.1343A>T p.Q448L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99507928; called by muse, mutect2, varscan2
- ZFYVE26 | c.5797A>T p.S1933C | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100720705; called by muse, mutect2, varscan2
- ZNF12 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV100703906; called by muse, mutect2, varscan2
- ZNF197 | c.2824A>T p.K942* | Nonsense Mutation (SNP) | VAF 51/180 reads (28%) | catalogued as COSV99940183; called by muse, mutect2, varscan2
- ZNF208 | c.1277A>T p.K426I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV101237217; called by muse, mutect2, varscan2
- ZNF415 | c.1358C>A p.S453* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV99702074; called by muse, mutect2, varscan2
- ZNF462 | c.7171A>T p.S2391C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99473409; called by muse, mutect2, varscan2
- ZNF594 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV101280583; called by muse, mutect2, varscan2
- ZNF615 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV100943992; called by muse, mutect2, varscan2
- ZNF618 | c.1235A>T p.Q412L (on ENST00000374126 / NM_001318042.2; = p.Q319L on NM_133374.2) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99931081; called by muse, mutect2, varscan2
- ZNF638 | c.5921A>T p.E1974V | Missense Mutation (SNP) | VAF 85/349 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100040063; called by muse, mutect2, varscan2
- ZNF98 | c.1136A>T p.K379M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100757635; called by muse, mutect2, varscan2
- ZZZ3 | c.301A>T p.I101L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100890459; called by muse, mutect2, varscan2
- ANXA9 | c.339_340delinsT p.T114Qfs*9 | Frame Shift Del (DEL) | VAF 23/187 reads (12%) | called by pindel, varscan2*
- CACNA1S | c.1619+2_1619+3del p.X540_splice | Splice Site (DEL) | VAF 34/264 reads (13%) | called by mutect2, pindel, varscan2
- GDF10 | c.688A>T p.R230W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- IGKV6D-41 | c.5T>A p.V2E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NASP | c.1435_1442del p.G479Rfs*3 | Frame Shift Del (DEL) | VAF 16/22 reads (73%) | called by pindel, varscan2
- PCDHB9 | c.132T>A p.F44L | Missense Mutation (SNP) | VAF 113/546 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PDRG1 | c.76del p.D26Tfs*19 | Frame Shift Del (DEL) | VAF 32/160 reads (20%) | called by mutect2, pindel, varscan2
- PI4KA | c.5818A>T p.I1940F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKDC | c.2648_2652delinsT p.Y883Lfs*9 | Frame Shift Del (DEL) | VAF 47/84 reads (56%) | called by pindel, varscan2*
- SIPA1 | c.2585_2608del p.T862_P869del | In Frame Del (DEL) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- SLC22A6 | c.332A>T p.Y111F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2
- TRIM60 | c.1287del p.Y429* | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTS13 | c.3847C>T p.L1283= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- ADAMTS3 | c.1530T>A p.P510= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV99712148; called by muse, mutect2, varscan2
- ALCAM | c.1296A>T p.T432= | Silent (SNP) | VAF 76/285 reads (27%) | catalogued as COSV100065814; called by muse, mutect2, varscan2
- ANKEF1 | c.2028A>G p.K676= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as rs199615882, COSV101001075; called by muse, mutect2, varscan2
- ARFGEF1 | c.318T>G p.L106= | Silent (SNP) | VAF 90/155 reads (58%) | catalogued as COSV99144972; called by muse, mutect2, varscan2
- ASH1L | c.2358A>T p.T786= | Silent (SNP) | VAF 33/311 reads (11%) | catalogued as COSV100853610; called by muse, mutect2, varscan2
- ASZ1 | c.396A>G p.V132= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99498332; called by muse, mutect2, varscan2
- ATG3 | c.381A>T p.T127= | Silent (SNP) | VAF 108/382 reads (28%) | catalogued as COSV99344408; called by muse, mutect2, varscan2
- ATP10B | c.816A>T p.R272= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100469766; called by muse, mutect2, varscan2
- ATP12A | c.2637A>T p.G879= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99518537; called by muse, mutect2, varscan2
- ATR | c.6492A>T p.I2164= | Silent (SNP) | VAF 48/186 reads (26%) | catalogued as COSV100638608; called by muse, mutect2, varscan2
- ATRAID | c.597A>T p.I199= (on ENST00000611786; = p.I86= on NM_016085.5) | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV99255802; called by muse, mutect2, varscan2
- BICD1 | c.384A>T p.A128= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV99863046; called by muse, mutect2, varscan2
- BIRC6 | c.3546A>T p.L1182= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs188040071, COSV101428971; called by muse, mutect2, varscan2
- BSG | c.423A>T p.T141= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100345044; called by muse, mutect2, varscan2
- C1QC | c.189A>T p.P63= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV101009558; called by muse, mutect2
- CAMSAP2 | c.2226A>T p.P742= (on ENST00000236925 / NM_001297707.2; = p.P731= on NM_203459.3) | Silent (SNP) | VAF 55/357 reads (15%) | catalogued as COSV99374386; called by muse, mutect2, varscan2
- CAPN13 | c.1287G>A p.S429= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs752920214, COSV54432498; called by muse, mutect2, varscan2
- CCDC144A | c.3999T>A p.P1333= | Silent (SNP) | VAF 50/179 reads (28%) | catalogued as COSV100138717; called by muse, mutect2, varscan2
- CCDC178 | c.618A>T p.S206= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100286916; called by muse, mutect2, varscan2
- CCDC180 | c.3084A>T p.I1028= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV100827343; called by muse, mutect2, varscan2
- CDH17 | c.1332T>C p.D444= | Silent (SNP) | VAF 246/336 reads (73%) | catalogued as COSV99218079; called by muse, mutect2, varscan2
- CDX2 | c.240C>T p.Y80= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV101122720; called by muse, mutect2, varscan2
- CEL | c.1194A>T p.P398= (on ENST00000673714; = p.P395= on NM_001807.6) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100672839; called by mutect2, varscan2
- CENPI | c.1890C>T p.F630= | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as COSV54501111, COSV54503042; called by mutect2, varscan2
- CEP112 | c.1053A>T p.L351= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101211150; called by muse, mutect2
- CHD2 | c.4575C>T p.H1525= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV101246053; called by muse, mutect2, varscan2
- CHD6 | c.873A>T p.A291= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100498728; called by muse, mutect2, varscan2
- CYP2R1 | c.564A>C p.S188= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100585008; called by muse, mutect2, varscan2
- DAG1 | c.2088A>T p.L696= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100445209; called by muse, mutect2, varscan2
- DOCK8 | c.1404T>A p.V468= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV101210358; called by muse, mutect2, varscan2
- EGFR | c.3594A>T p.L1198= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV99295287; called by muse, mutect2, varscan2
- EP400 | c.1374A>T p.G458= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as COSV100202363; called by muse, mutect2, varscan2
- ERICH3 | c.2529A>T p.A843= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100445889; called by muse, mutect2, varscan2
- ESPL1 | c.5262G>T p.L1754= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99229816; called by muse, mutect2, varscan2
- FAM216B | c.138T>A p.I46= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100573098; called by muse, mutect2, varscan2
- FAM24A | c.234T>A p.S78= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV100925092; called by muse, mutect2, varscan2
- FER1L6 | c.4518T>C p.F1506= | Silent (SNP) | VAF 97/187 reads (52%) | catalogued as COSV101206217, COSV67549278; called by muse, mutect2, varscan2
- FLG | c.3555A>T p.V1185= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as COSV100912260; called by muse, mutect2, varscan2
- GAD2 | c.822T>C p.I274= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99394094; called by muse, mutect2, varscan2
- GOLGA4 | c.486A>T p.T162= | Silent (SNP) | VAF 70/268 reads (26%) | catalogued as COSV100729185; called by muse, mutect2, varscan2
- GUCY2F | c.2889T>A p.S963= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV99485708; called by muse, mutect2, varscan2
- HBEGF | c.99A>T p.L33= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs375401691; called by muse, mutect2, varscan2
- HMCN1 | c.7551G>T p.G2517= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs777179177, COSV99625584, COSV99629775; called by muse, mutect2, varscan2
- ICOS | c.288A>G p.L96= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as rs372256111; called by muse, mutect2, varscan2
- IGHV1-58 | c.216T>A p.V72= | Silent (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- IL7R | c.720T>A p.P240= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV100286698; called by muse, mutect2, varscan2
- KDM3B | c.3759A>T p.S1253= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100070264; called by muse, mutect2, varscan2
- KIAA1109 | c.10953A>T p.A3651= | Silent (SNP) | VAF 95/241 reads (39%) | catalogued as COSV99177232; called by muse, mutect2, varscan2
- KIAA1217 | c.747T>C p.D249= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1248556679, COSV100908417; called by muse, mutect2, varscan2
- LRRC17 | c.174A>T p.T58= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV99978693; called by muse, mutect2, varscan2
- LYST | c.8262A>T p.P2754= | Silent (SNP) | VAF 31/207 reads (15%) | catalogued as COSV101090353; called by muse, mutect2, varscan2
- MAGI1 | c.1176A>G p.L392= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100443199; called by muse, mutect2
- MARVELD2 | c.636A>T p.T212= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as COSV100347959; called by muse, mutect2, varscan2
- MIA3 | c.1290A>T p.S430= | Silent (SNP) | VAF 75/562 reads (13%) | catalogued as COSV100719546; called by muse, mutect2, varscan2
- MSANTD2 | c.1620A>T p.A540= (on ENST00000374979 / NM_001308027.2; = p.A488= on NM_024631.4) | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV99516002; called by muse, mutect2, varscan2
- MUC16 | c.26190T>A p.S8730= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV101201826; called by muse, mutect2, varscan2
- MUC17 | c.3150C>T p.S1050= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as rs1466998994, COSV100075143; called by muse, varscan2
- MYCBP2 | c.4692G>T p.L1564= (on ENST00000357337; = p.L1602= on NM_015057.5) | Silent (SNP) | VAF 51/73 reads (70%) | catalogued as COSV100631993; called by muse, mutect2, varscan2
- MYH1 | c.2046T>A p.T682= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV99876958, COSV99877248; called by muse, mutect2, varscan2
- MYO19 | c.1944C>A p.T648= (on ENST00000614623 / NM_001163735.1; = p.T448= on NM_025109.5) | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- NME8 | c.1632A>T p.A544= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV99553889; called by muse, mutect2, varscan2
- NOSTRIN | c.366A>T p.T122= (on ENST00000317647 / NM_001039724.4; = p.T44= on NM_052946.3) | Silent (SNP) | VAF 51/227 reads (22%) | catalogued as COSV100474111; called by muse, mutect2, varscan2
- NPHS2 | c.432T>A p.P144= | Silent (SNP) | VAF 70/461 reads (15%) | catalogued as COSV100858214; called by muse, mutect2, varscan2
- NRSN2 | c.315A>T p.A105= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV101206814; called by muse, mutect2, varscan2
- OR2M7 | c.828A>G p.V276= | Silent (SNP) | VAF 35/262 reads (13%) | catalogued as COSV100522707; called by muse, mutect2, varscan2
- OR51B6 | c.375C>T p.R125= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV100972082; called by muse, mutect2, varscan2
- OR5D18 | c.381T>A p.I127= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV61739089; called by muse, mutect2, varscan2
- OR6C68 | c.726T>C p.H242= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs776110341, COSV101110062; called by muse, mutect2, varscan2
- OR7A17 | c.720C>A p.T240= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs758846647, COSV100541712; called by muse, mutect2, varscan2
- PARVB | c.780C>A p.L260= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100115256; called by muse, mutect2, varscan2
- PCDHB3 | c.1092A>T p.V364= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99166764; called by muse, mutect2, varscan2
- PCDHGC4 | c.1137A>T p.S379= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV99342474; called by muse, mutect2, varscan2
- PDCD6IP | c.159A>T p.A53= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV100219191; called by muse, mutect2, varscan2
- PDE2A | c.2163T>A p.S721= | Silent (SNP) | VAF 47/196 reads (24%) | catalogued as COSV100558425; called by muse, varscan2
- PDE4DIP | c.5325C>A p.A1775= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs376826439, COSV100521948; called by muse, mutect2, varscan2
- PHLDB1 | c.2355A>T p.T785= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV100616808; called by muse, mutect2, varscan2
- PITPNM3 | c.1746A>T p.T582= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99339117; called by muse, mutect2, varscan2
- PKP3 | c.1233A>G p.T411= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs1477310764, COSV100520959; called by muse, mutect2, varscan2
- PRAM1 | c.936C>T p.A312= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs760589066, COSV55314172; called by muse, mutect2, varscan2
- PTGS2 | c.1263T>A p.A421= | Silent (SNP) | VAF 33/270 reads (12%) | catalogued as COSV100821853; called by muse, mutect2, varscan2
- PTPN13 | c.1335T>A p.G445= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100365487; called by muse, mutect2, varscan2
- PTPRA | c.1392A>T p.T464= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV99400687; called by muse, mutect2, varscan2
- PTPRB | c.1182T>A p.L394= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV99719077; called by muse, mutect2, varscan2
- RECQL4 | c.2286G>A p.Q762= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV99468277; called by muse, mutect2
- RIOX2 | c.78A>T p.A26= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100328622; called by muse, mutect2, varscan2
- SEMA3D | c.1425T>A p.T475= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99407475; called by muse, mutect2, varscan2
- SIX4 | c.1200T>A p.I400= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV99382544; called by muse, mutect2, varscan2
- STC2 | c.837T>A p.L279= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99438727; called by muse, mutect2, varscan2
- TAF1L | c.2880C>A p.A960= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as COSV99645446; called by muse, mutect2, varscan2
- TEKT1 | c.603T>A p.S201= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100106460; called by muse, mutect2, varscan2
- TESMIN | c.387A>T p.L129= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV54831714; called by muse, mutect2, varscan2
- TIGD4 | c.1317A>T p.I439= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV100428077; called by muse, mutect2, varscan2
- TKT | c.1317A>T p.S439= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99965179; called by muse, mutect2, varscan2
- TMPRSS13 | c.102A>C p.A34= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV101471505; called by muse, mutect2, varscan2
- TNFRSF8 | c.1089G>A p.T363= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs1288037514, COSV55799873, COSV99821957; called by muse, mutect2, varscan2
- TNPO2 | c.1128A>T p.S376= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100790421; called by muse, mutect2, varscan2
- TPRA1 | c.363C>T p.T121= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as COSV99952457; called by muse, mutect2, varscan2
- TRIM25 | c.780A>T p.T260= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV100381165; called by muse, mutect2, varscan2
- TRIP12 | c.5430T>C p.D1810= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1232128293, COSV99390979; called by muse, mutect2, varscan2
- TSC22D1 | c.1914A>T p.T638= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101488192; called by muse, mutect2, varscan2
- TTN | c.27384T>A p.I9128= (on ENST00000591111; = p.I8201= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100631407; called by muse, mutect2
- TUSC1 | c.327C>T p.S109= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100787861; called by muse, mutect2, varscan2
- UNC13B | c.4362A>T p.T1454= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV100266905; called by muse, mutect2, varscan2
- VENTX | c.762G>A p.T254= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs528996055, COSV58085110; called by muse, mutect2, varscan2
- VGF | c.702T>A p.R234= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99973227; called by muse, mutect2, varscan2
- WDR5 | c.921A>T p.T307= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100682055; called by muse, mutect2, varscan2
- WNT3A | c.750C>T p.R250= | Silent (SNP) | VAF 17/183 reads (9%) | catalogued as COSV99470202; called by muse, mutect2
- XDH | c.843A>T p.P281= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV101052479; called by muse, mutect2, varscan2
- ZNF665 | c.1242T>A p.I414= (on ENST00000600412; = p.I479= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV101128833; called by muse, mutect2, varscan2
- ZPBP | c.24A>T p.P8= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99250598; called by muse, mutect2, varscan2
- CHRNA10 | c.*2G>T | 3'UTR (SNP) | VAF 21/74 reads (28%) | catalogued as rs753818191, COSV99167265; called by muse, mutect2, varscan2
- DCHS2 | n.8188A>T | RNA (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100602707; called by muse, mutect2, varscan2
- DEPDC5 | c.*526A>T | 3'UTR (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99836639; called by muse, mutect2, varscan2
- FAM153CP | n.360T>A | RNA (SNP) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- H2BP2 | n.1062-351A>C | Intron (SNP) | VAF 49/617 reads (8%) | called by muse, mutect2
- HBD | chr11:5232736 G>T | 3'Flank (SNP) | VAF 25/82 reads (30%) | catalogued as rs764058749, COSV99496890; called by muse, mutect2, varscan2
- OR5AU1 | c.-72A>T | 5'UTR (SNP) | VAF 28/110 reads (25%) | catalogued as COSV100436222; called by muse, mutect2, varscan2
- PCDHGA3 | c.2424+23T>C | Intron (SNP) | VAF 65/336 reads (19%) | called by muse, mutect2, varscan2
- SLC22A17 | n.660T>A | RNA (SNP) | VAF 75/245 reads (31%) | catalogued as COSV99249073; called by muse, mutect2, varscan2
- TMC5 | c.1049-3330A>C | Intron (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99572896; called by muse, mutect2, varscan2
- TPM3 | chr1:154157711 T>C | 3'Flank (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99666678; called by muse, mutect2, varscan2
